Somatic mutation profile of tumor specimen MBCProject_0852_T2_WES (aliquot MBCProject_0852_T2_WES_1) from CMI case MBCProject_0852, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.8 years (18,184 days).
Specimen MBCProject_0852_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2909e33b-3a4e-40cb-bc93-e793225f1d25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0852_SALIVA (Saliva), aliquot MBCProject_0852_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f72c90-a92b-4f3a-82dc-ec43208711ec

The open-access MAF lists 196 somatic variants for this specimen: 136 protein-altering or splice-affecting, 36 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 36, Intron 9, RNA 6, Splice Site 5, Nonsense Mutation 5, Frame Shift Del 4, 5'UTR 3, Splice Region 3, 3'UTR 3, 5'Flank 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 72/167 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762137050, COSV51621604; called by muse, mutect2, varscan2
- AC004593.2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs377591268; called by muse, varscan2
- ACVR2B | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs776754289, COSV61701092; called by muse, mutect2, varscan2
- ADAMTS15 | c.2764G>T p.G922C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV54503749; called by muse, mutect2
- ALMS1 | c.583T>G p.L195V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs777906149; called by muse, mutect2, varscan2
- AMZ1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs773979262; called by muse, varscan2
- CCDC186 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV65161760; called by muse, mutect2, varscan2
- CES4A | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs529170797; called by muse, mutect2, varscan2
- CFHR5 | c.1236A>T p.K412N | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56820377; called by muse, mutect2
- CMTM7 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58550058; called by muse, mutect2, varscan2
- CSMD3 | c.3772C>A p.P1258T (on ENST00000297405 / NM_001363185.1; = p.P1154T on NM_052900.3) | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52324820; called by muse, mutect2, varscan2
- CYP2D7 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63852216; called by muse, varscan2
- CYP4F12 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200041881, COSV61173156; called by muse, mutect2, varscan2
- DDX3X | c.278G>A p.G93E (on ENST00000399959; = p.G94E on NM_001356.5) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1374495935, COSV67864041; called by muse, mutect2, varscan2
- DNAH8 | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs267601015, COSV100543697, COSV59422745; called by muse, mutect2, varscan2
- GPR18 | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs775292571; called by muse, mutect2, varscan2
- GYPA | c.137-7T>C | Splice Region (SNP) | VAF 31/130 reads (24%) | catalogued as rs1270978859; called by muse, mutect2, varscan2
- HRNR | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.146); catalogued as COSV64254203; called by muse, mutect2, varscan2
- IGFL1 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV71443589; called by muse, mutect2, varscan2
- IQGAP2 | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV99167020; called by muse, mutect2, varscan2
- KRTAP4-2 | c.94_108del p.T33_R37del | In Frame Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs766817129; called by mutect2, varscan2
- MYMK | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs780606963, COSV60601648; called by muse, mutect2, varscan2
- OBSCN | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.981); catalogued as rs1327795074; called by muse, mutect2, varscan2
- OR2B3 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV65851003; called by muse, mutect2, varscan2
- OR2T33 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100531971, COSV58815594, COSV58817591; called by muse, varscan2
- PCDHGB2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs779307225; called by muse, mutect2, varscan2
- PHF8 | c.2923G>C p.E975Q (on ENST00000357988 / NM_001184896.1; = p.E939Q on NM_015107.3) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1414664364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.8533C>T p.H2845Y | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV65750446; called by muse, mutect2, varscan2
- PRSS1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61197679; called by muse, mutect2
- PTP4A3 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs888702341; called by muse, mutect2, varscan2
- RBMXL3 | c.2688T>G p.S896R | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.766); catalogued as COSV104395695; called by muse, mutect2, varscan2
- SCN4A | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as rs1429665339; called by muse, mutect2, varscan2
- SCUBE1 | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV62614042; called by muse, mutect2, varscan2
- SEPTIN2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs191642496, COSV100764913; called by muse, mutect2, varscan2
- SETD5 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs567415895; called by muse, mutect2, varscan2
- SSTR2 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs139033946; called by muse, mutect2, varscan2
- STAM2 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV99813177; called by muse, mutect2
- STARD8 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs201149959; called by muse, mutect2, varscan2
- TMC7 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100432681; called by muse, mutect2, varscan2
- TSPAN31 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs763198055, COSV57276750, COSV99226038; called by muse, mutect2, varscan2
- ZBTB33 | c.1283C>A p.S428* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | catalogued as COSV58534689; called by muse, mutect2, varscan2
- ABCC6 | c.1116C>G p.Y372* | Nonsense Mutation (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- ADCY2 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADCY9 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGT | c.54G>C p.R18S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.038); called by mutect2, varscan2
- ANKRD2 | c.397_410del p.S133Pfs*12 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP39 | c.2637G>C p.K879N (on ENST00000276826 / NM_001308208.2; = p.K910N on NM_025251.2) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARMC4 | c.1429A>G p.R477G | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ARMC7 | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- ATP4A | c.1916C>G p.A639G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP8B4 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BIRC3 | c.267G>C p.L89F | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2
- BIRC3 | c.269A>T p.Y90F | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.346); called by muse, mutect2
- BRCA1 | c.3254G>T p.R1085I | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- C11orf45 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- C7orf25 | c.-21G>A | Splice Region (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- CCDC7 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.038); called by muse, mutect2
- CCDC88A | c.2059T>G p.F687V | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL16 | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CDH6 | c.1115T>A p.I372N | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CECR2 | c.3173G>T p.G1058V (on ENST00000342247 / NM_001290047.2; = p.G874V on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CFAP45 | c.1531C>G p.R511G | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CNTN1 | c.2980_2980+12del p.X994_splice | Splice Site (DEL) | VAF 21/228 reads (9%) | called by mutect2, pindel
- COL1A1 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP2 | c.3190G>T p.G1064W (on ENST00000616178 / NM_001291722.2; = p.G1039W on NM_014376.4) | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP11B2 | c.1505T>C p.I502T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CYP4F3 | c.968A>C p.D323A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- DEF6 | c.795C>A p.H265Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DLG1 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DNM3 | c.1148A>C p.E383A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DST | c.17233C>G p.L5745V (on ENST00000361203 / NM_001374722.1; = p.L3442V on NM_015548.5) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, varscan2
- EML1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ENPP6 | c.1171G>C p.V391L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPPK1 | c.2177C>A p.T726K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVA1B | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FER1L6 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FMO5 | c.682T>A p.Y228N | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FREM3 | c.4225A>C p.T1409P | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GC | c.1165-1G>C p.X389_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- GCNT2 | c.973G>A p.A325T (on ENST00000379597 / NM_001374747.1; = p.A323T on NM_001491.3) | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GLT8D1 | c.921C>G p.H307Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GRIN2A | c.899C>A p.T300N | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- GRIN2A | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GTF3C4 | c.503G>C p.S168T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HAPLN2 | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- IFT122 | c.1772A>G p.Q591R (on ENST00000348417 / NM_052989.3; = p.Q532R on NM_018262.4) | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IKBKE | c.1556G>C p.S519T | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ING3 | c.267+4A>T | Splice Region (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- INTS6L | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KRTAP13-3 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KSR1 | c.670G>T p.G224C (on ENST00000644974 / NM_001367810.1; = p.G87C on NM_014238.2) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LARGE1 | c.1797_1810del p.L600Vfs*48 | Frame Shift Del (DEL) | VAF 24/196 reads (12%) | called by mutect2, pindel
- MROH2B | c.3248A>G p.D1083G | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MUC12 | c.13222G>T p.A4408S (on ENST00000379442; = p.A4265S on NM_001164462.1) | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.15); called by muse, mutect2
- MYT1L | c.2009C>A p.P670H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- NAP1L1 | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NET1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NEURL4 | c.4042G>T p.E1348* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- NIN | c.3866G>C p.R1289T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- NLGN3 | c.982G>C p.V328L (on ENST00000358741 / NM_181303.2; = p.V308L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP8 | c.1488T>G p.I496M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NMNAT2 | c.821+2T>A p.X274_splice | Splice Site (SNP) | VAF 26/213 reads (12%) | called by muse, mutect2, varscan2
- NPC1L1 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- NRIP1 | c.523T>A p.L175I | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- OR10Z1 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OTUD6A | c.453C>A p.H151Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDCD1 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PENK | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PGRMC1 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRTG | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.251); called by muse, varscan2
- PSMC2 | c.1145-2A>T p.X382_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- RABGAP1L | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM47 | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD3 | c.2229_2245del p.K744Sfs*9 | Frame Shift Del (DEL) | VAF 58/310 reads (19%) | called by mutect2, pindel
- RGPD3 | c.1730T>A p.V577E | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- RRM2 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RTL9 | c.695T>A p.L232* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1741T>A p.W581R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAMBP | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- STARD9 | c.8431C>A p.H2811N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TAF7L | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TBC1D30 | c.1436G>T p.C479F (on ENST00000542120; = p.C316F on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by mutect2, varscan2
- TG | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TGFBR3 | c.538_568+6del p.X180_splice | Splice Site (DEL) | VAF 38/387 reads (10%) | called by mutect2, pindel
- TKT | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TNRC6A | c.4163G>T p.G1388V | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRIM2 | c.1781A>G p.N594S (on ENST00000437508; = p.N621S on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- TTC28 | c.6794A>C p.Q2265P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A2 | c.272A>C p.N91T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UROD | c.219_253del p.R75Hfs*44 | Frame Shift Del (DEL) | VAF 47/336 reads (14%) | called by mutect2, pindel
- WFS1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ZNF207 | c.600_620del p.L201_P207del | In Frame Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel
- ZNF75D | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ZNF75D | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADAMTS7 | c.2046T>G p.A682= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ATP2B4 | c.1212G>A p.Q404= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs757808165; called by muse, mutect2, varscan2
- ATP8B1 | c.1350T>C p.Y450= | Silent (SNP) | VAF 68/179 reads (38%) | called by muse, mutect2, varscan2
- CCDC3 | c.714G>T p.L238= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- CDK10 | c.816C>T p.V272= (on ENST00000353379 / NM_052988.5; = p.V201= on NM_052987.4) | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs370962699; called by muse, mutect2, varscan2
- CENPC | c.2409C>T p.N803= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs374931553; called by muse, mutect2, varscan2
- CMPK2 | c.363C>G p.G121= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- COL9A1 | c.1038T>A p.P346= | Silent (SNP) | VAF 25/289 reads (9%) | called by muse, mutect2
- COMMD5 | c.624A>C p.L208= | Silent (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- DCDC1 | c.4554C>T p.S1518= (on ENST00000597505 / NM_001367979.1; = p.S625= on NM_020869.3) | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs1237416222, COSV58002645; called by muse, mutect2, varscan2
- DNAH2 | c.222A>G p.A74= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- EPB41L3 | c.3135A>C p.A1045= | Silent (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- FAM83C | c.1437G>A p.L479= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV65583356; called by muse, varscan2
- FSTL1 | c.444C>A p.I148= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1308C>T p.N436= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- GSTA3 | c.345G>A p.E115= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV99274398; called by muse, mutect2
- IGKV4-1 | c.93G>C p.L31= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs552609031; called by muse, mutect2
- KMT2D | c.3528A>G p.A1176= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- MCF2 | c.2413A>C p.R805= | Silent (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- PATZ1 | c.96G>A p.Q32= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1426174769; called by muse, mutect2, varscan2
- PPP2R3B | c.654C>T p.V218= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- PRKCSH | c.393C>T p.A131= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs780423740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF138 | c.648A>G p.Q216= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs773379320; called by muse, mutect2
- SETX | c.4143A>C p.A1381= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as rs1053045962; called by muse, mutect2, varscan2
- SLC4A4 | c.2043C>T p.L681= (on ENST00000264485 / NM_001098484.3; = p.L637= on NM_003759.4) | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs754449686; called by muse, mutect2, varscan2
- SPTBN4 | c.1105C>T p.L369= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- SYCP1 | c.864G>T p.L288= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs575173003; called by muse, varscan2
- SYNE1 | c.849T>G p.P283= (on ENST00000367255 / NM_182961.4; = p.P290= on NM_033071.3) | Silent (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- TIGAR | c.636C>T p.D212= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as rs775799671; called by muse, mutect2, varscan2
- TMEM87A | c.1359C>T p.L453= | Silent (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- USP24 | c.1488T>C p.I496= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- VCAM1 | c.1914A>G p.K638= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- VCAN | c.2376T>A p.T792= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV54112172; called by muse, mutect2, varscan2
- VIM | c.702G>A p.L234= | Silent (SNP) | VAF 109/357 reads (31%) | catalogued as COSV99812944; called by muse, mutect2, varscan2
- WDR17 | c.1458T>C p.I486= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- YTHDF1 | c.69A>G p.L23= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- ACTRT3 | chr3:169764897 T>C | 3'Flank (SNP) | VAF 21/239 reads (9%) | called by muse, mutect2
- AHSA2P | n.4C>G | RNA (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- AL353804.4 | chrX:73823440 G>A | 5'Flank (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- BHLHE40-AS1 | n.898T>A | RNA (SNP) | VAF 15/229 reads (7%) | called by muse, mutect2
- C12orf77 | n.416_426del | RNA (DEL) | VAF 25/124 reads (20%) | called by mutect2, pindel, varscan2
- C14orf177 | n.690T>A | RNA (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- FAM50A | c.829+13G>A | Intron (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922595 T>G | 5'Flank (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- KIAA0930 | c.65-192G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- LAMA1 | c.8095-30C>T | Intron (SNP) | VAF 53/290 reads (18%) | catalogued as rs567274914, COSV101057341; called by muse, mutect2, varscan2
- MIR520G | n.55del | RNA (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- PAPOLG | c.-89C>T | 5'UTR (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- PLA2R1 | c.-16A>T | 5'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs772389901; called by muse, mutect2, varscan2
- PPP2R3B | c.1036+386C>A | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- PSMD1 | c.-64G>C | 5'UTR (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- RAD51D | c.*677G>C | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- RPL10 | c.*133C>T | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs782160948; called by muse, varscan2
- RPS21 | c.186+25_186+43del | Intron (DEL) | VAF 27/170 reads (16%) | called by mutect2, pindel
- SHB | c.838+545T>G | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- TLX1NB | n.1593C>A | RNA (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- TMEM154 | c.*12G>A | 3'UTR (SNP) | VAF 28/123 reads (23%) | catalogued as rs183698300; called by muse, mutect2, varscan2
- TTLL1 | c.114-337G>C | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, varscan2
- TTN | c.10361-4427C>T | Intron (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2517T>A | Intron (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
